Surgical pathology report (de-identified scan), TCGA case TCGA-85-8052, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-8052-01A (Primary Tumor).

[page 1 of 2]
TCGA Pathology Reports

	OpenClinica ID	Gross Description	Microscopic Description	Diagnosis Details	Comments
ID					

[page 2 of 2]
Formatted Path Report	Laterality/Location		Date of excision
LUNG TISSUE CHECKLIST Specimen type: Lobectomy Tumor site: Lung Tumor size: 5 x 2 x 7.5 cm Histologic type: Squamous cell carcinoma Histologic grade: Moderately differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: Not specified Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None	Right- upper		

Source: NCI Genomic Data Commons file ace32fe2-94ee-457b-a1f2-2639a15aad16 (TCGA-85-8052.EBD98864-F24A-4773-8FBA-51C2B23BBBD4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).